MMRF case MMRF_2817 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7b9d00ba-5027-4c54-904e-ef63e276fb63

Demographics
Sex at birth: female; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.6 years (20,663 days); ISS stage: III; Days to last known disease status: 158 days; Days to last follow up: 158 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -18, day 158.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Hemoglobin 7.32 mmol/L.
- Absolute Neutrophil 2.5 ×10⁹/L.
- Serum Free Immunoglobulin Light Chain, Lambda 11.6 mg/dL.
- M Protein 5.55 g/dL.
- Calcium 2.37 mmol/L.
- Lactate Dehydrogenase 5.35 µkat/L.
- Creatinine 83.1 µmol/L.
- Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL.
- Platelets 160 ×10⁹/L.
- Albumin 36 g/L.
- Beta 2 Microglobulin 6.2 µg/mL.

Other clinical attributes
- Day -18: Weight: 59 kg; Height: 160 cm.

Biospecimens (2 samples)
- Sample MMRF_2817_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_2817_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
